Somatic mutation profile of tumor specimen TCGA-DJ-A2PY-01A (aliquot TCGA-DJ-A2PY-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2PY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 46.7 years (17,056 days).
Specimen TCGA-DJ-A2PY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0941857-b1d2-46c5-88ea-c9dd5b69a47b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PY-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PY-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34935d69-c32c-4c26-bf22-fb5fb1676d88

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MYOM2 | c.2426C>T p.T809I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1221779722, COSV50703911; called by muse, mutect2
- NDUFA6 | c.281_284del p.I94Kfs*44 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs768463498; called by mutect2, pindel, varscan2
- SRR | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as rs147900333; called by muse, mutect2, varscan2
- ARHGAP33 | c.1837_1855del p.G613Rfs*13 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- CLSTN1 | c.1290C>T p.L430= (on ENST00000377298 / NM_001009566.3; = p.L420= on NM_014944.4) | Silent (SNP) | VAF 6/129 reads (5%) | catalogued as rs1383105875, COSV63646905; called by muse, mutect2
- ITGA8 | c.1455G>T p.P485= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs200613964, COSV65225741; called by muse, mutect2, varscan2
- SGK1 | c.174G>A p.L58= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV52805684, COSV52808137; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.705C>T p.S235= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs188342632, COSV59129479; called by muse, mutect2, varscan2
